TCGA case TCGA-29-1766 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Retroperitoneum and peritoneum; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/01ea6354-137b-47f3-9021-a01a382b1147

Demographics
Sex at birth: female; Race: white; Age at index: 74 years; Vital status: Dead; Days to death: 1,199 days (3.3 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C48.2; Tissue or organ of origin: Peritoneum, NOS; Site of resection or biopsy: Ovary; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 74.9 years (27,359 days); Year of diagnosis: 2006; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G2; Prior treatment: No.
   Pathology details: Residual tumor measurement: 11-20 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Treatment intent type: Adjuvant; Days to treatment start: 39 days; Days to treatment end: 196 days; Number of cycles: 11; Treatment dose: 19,590 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 98 days; Days to treatment end: 189 days; Number of cycles: 4; Treatment dose: 1,580 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Progressive Disease; Days to treatment start: 224 days; Days to treatment end: 406 days (1.1 years); Number of cycles: 9; Treatment dose: 320 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 685 days (1.9 years); Days to treatment end: 727 days (2.0 years); Number of cycles: 3; Treatment dose: 6 AUC; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 825 days (2.3 years); Days to treatment end: 909 days (2.5 years); Number of cycles: 4; Treatment dose: 75 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Progressive Disease; Days to treatment start: 1,084 days (3.0 years); Days to treatment end: 1,112 days (3.0 years); Number of cycles: 4; Treatment dose: 5 mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 76.7 years (28,031 days); Days to diagnosis: 672 days (1.8 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (4 entries)
- Day 672 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 672 days (1.8 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 1,190 days (3.3 years); Disease response: With Tumor.
- Days to follow up: 1,199 days (3.3 years); Disease response: With Tumor.
- ECOG performance status: 0; Timepoint: Post Adjuvant Therapy.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-29-1766-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.3; Intermediate dimension: 0.5; Shortest dimension: 0.4.
  Slide TCGA-29-1766-01A-01-BS1: Section location: Bottom; Percent tumor cells: 40; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 50.
  Slide TCGA-29-1766-01A-01-TS1: Section location: Top; Percent tumor cells: 55; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 40; Percent lymphocyte infiltration: 2.
- Sample TCGA-29-1766-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Peritoneum ovary; Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Performance status timing: Post-Adjuvant Therapy; Anatomic organ subdivision: Right; Method initial path diagnosis: Tumor resection.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 3: Therapy regimen: Progression.
- Drug treatment 5: Pharmaceutical therapy drug name: Doxil; Therapy regimen: Progression.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,199 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,199 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 672 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-29-1766-01A-01D-0559-01): tumor purity 0.55, ploidy 4.24, whole-genome doublings 2.
